Surgical pathology report (de-identified scan), TCGA case TCGA-Z6-A9VB, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Cureline, specimen TCGA-Z6-A9VB-01A (Primary Tumor).

Case #:

Patient: **Age (years):** **Gender:** M

Clinical diagnosis: Squamous cell carcinoma of the esophagus

Date of procurement:

Sample: histology #

Gross description: Esophageal fragment with gastric patch 12,5 cm. Gastric patch – 1,5 cm. Esophageal mucosa shows infiltrative oval ulcerated tumor 4x1,5 cm, 4,5 from proximal resection line and 4 cm from distal resection line. . Section reveals gray tumor mass 1 cm in thickness Paraesophageal adipose tissue contains 25 consolidations 0,3-0,7 cm in diameter. Paraesophageal lymphatic node 1,5x0,4 cm with dark-red surface .

Microscopic description: Sections reveal ulcerative infiltrated tumor, moderately differentiated squamous cell carcinoma, infiltrating all laminae and adventitia. Surgical borders are clear. Paraesophageal lymphatic node shows metastatic cells. Paragastric lymphatic nodes and greater omentum show no sign of metastasis.

Final diagnosis: Moderately differentiated squamous cell carcinoma of the esophagus .

ICD-O-3

Carcinoma, squamous cell NOS 8670/3
Site: Esophagus, distal third C15.5
J01/27/14

Confidential

Source: NCI Genomic Data Commons file 9926feb4-17fa-4c71-8498-0d2dbf246080 (TCGA-Z6-A9VB.C5F85421-4EA0-4E94-B8B6-0096AB4C3A2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).